Somatic mutation profile of tumor specimen 0DRIW6 from CCDI case PBCGHV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Cerebrum; Age at diagnosis: 1.0 years (374 days).
Specimen 0DRIW6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de535eb0-572e-4bb3-8d7c-41098ae14e23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d198249-3d0d-432d-9bed-837e7fdc973a

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 235/479 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EMILIN2 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs777010464; called by muse, mutect2
- OSBPL10 | c.457+4C>T | Splice Region (SNP) | VAF 140/299 reads (47%) | catalogued as rs1166910227; called by muse, mutect2, varscan2
- SEMA3F | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99137198; called by muse, mutect2
- FEZ2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 306/644 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- HECTD1 | c.4334G>C p.S1445T | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); called by muse, mutect2
- CAMK1D | c.870C>T p.H290= | Silent (SNP) | VAF 72/800 reads (9%) | catalogued as rs764307882, COSV101124009; called by muse, mutect2
- CLCA1 | c.2640G>A p.T880= | Silent (SNP) | VAF 26/438 reads (6%) | catalogued as rs771181835; called by muse, mutect2
- PAF1 | c.1530G>A p.S510= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as rs768378595, COSV55394237; called by muse, mutect2, varscan2
